CCDI case PBBXAT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/05e62bd0-1d29-4aa9-b639-496e3817864c

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 9.9 years (3,612 days).

Biospecimens (3 samples)
- Sample 0DJHE2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJHEK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJHG4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
